Somatic mutation profile of tumor specimen TCGA-CV-7422-01A (aliquot TCGA-CV-7422-01A-21D-2078-08) from TCGA case TCGA-CV-7422, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 60.5 years (22,098 days).
Specimen TCGA-CV-7422-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 04c02ed0-9743-4dbb-b48d-afd01614a655.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7422-10A (Blood Derived Normal), aliquot TCGA-CV-7422-10A-01D-2078-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e566d7a2-8280-4e65-91db-2cdb4b9b5cc3

The open-access MAF lists 151 somatic variants for this specimen: 109 protein-altering or splice-affecting, 37 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 92, Silent 37, Nonsense Mutation 11, Splice Site 3, RNA 3, 3'Flank 1, Frame Shift Del 1, In Frame Ins 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 26/79 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.310C>T p.Q104* | Nonsense Mutation (SNP) | VAF 20/79 reads (25%) | hotspot (GDC flag); catalogued as rs1567555934, COSV52694629; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACAP3 | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100686262; called by muse, mutect2, varscan2
- AL163195.3 | c.131+2T>G p.X44_splice | Splice Site (SNP) | VAF 17/79 reads (22%) | catalogued as COSV100250486; called by muse, mutect2, varscan2
- APOB | c.6145C>T p.P2049S | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99264921, COSV99267989; called by muse, mutect2
- ARID1A | c.5839C>T p.Q1947* | Nonsense Mutation (SNP) | VAF 20/99 reads (20%) | catalogued as COSV61380856; called by muse, mutect2, varscan2
- ASTN2 | c.1424G>A p.G475E (on ENST00000313400 / NM_001365069.1; = p.G424E on NM_014010.5) | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139435569, COSV57825016; called by muse, mutect2
- ATP2B1 | c.1987G>A p.E663K | Missense Mutation (SNP) | VAF 27/173 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as COSV99665460; called by muse, mutect2, varscan2
- BSX | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1018888705, COSV58006678; called by mutect2, varscan2
- C5orf22 | c.43C>G p.P15A | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV100323444; called by muse, mutect2, varscan2
- C8B | c.667-1G>T p.X223_splice | Splice Site (SNP) | VAF 8/34 reads (24%) | catalogued as rs200785263, COSV100980745; called by muse, mutect2, varscan2
- CA10 | c.931C>G p.P311A | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV53354695, COSV99562437; called by muse, mutect2, varscan2
- CASR | c.649G>A p.D217N | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as rs201091657; ClinVar: uncertain significance; called by muse, mutect2
- CCNF | c.855G>T p.Q285H | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV99563488; called by muse, mutect2
- CCT8L2 | c.1593G>T p.E531D | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV63463773; called by muse, mutect2, varscan2
- CDK5RAP2 | c.3496G>A p.G1166R | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100575314; called by muse, mutect2, varscan2
- CENPI | c.1987A>T p.I663F | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV99515246; called by muse, mutect2
- CFAP43 | c.873G>T p.K291N | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.112); catalogued as COSV99530590; called by muse, mutect2, varscan2
- CNNM1 | c.1331C>G p.S444* | Nonsense Mutation (SNP) | VAF 9/62 reads (15%) | catalogued as COSV100763821; called by muse, mutect2, varscan2
- COL6A1 | c.1063C>A p.Q355K | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.755); catalogued as COSV100720102; called by muse, mutect2
- CUBN | c.2255A>T p.H752L | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as COSV100912420; called by muse, mutect2, varscan2
- DCAF8L1 | c.1185C>G p.C395W | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101491434, COSV71595269; called by muse, mutect2, varscan2
- DIS3 | c.722T>G p.I241R | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV100899858; called by muse, mutect2, varscan2
- DOCK11 | c.5820G>C p.M1940I | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV99353524; called by muse, mutect2, varscan2
- DOP1A | c.1400T>A p.L467* | Nonsense Mutation (SNP) | VAF 17/213 reads (8%) | catalogued as COSV99381578; called by muse, mutect2
- DYRK1B | c.761C>A p.A254D | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as COSV100546540; called by muse, mutect2, varscan2
- ELL | c.37T>C p.S13P | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99443014; called by muse, mutect2
- EPHA10 | c.196G>C p.E66Q | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100139893, COSV60405019; called by muse, mutect2, varscan2
- EPHX2 | c.1478C>A p.A493E | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200893629, COSV100994553; called by muse, mutect2
- FBP2 | c.417C>G p.I139M | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100942103; called by muse, mutect2, varscan2
- GPR142 | c.776C>A p.A259D | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.045); catalogued as COSV100170712, COSV59518631; called by muse, mutect2
- GPR182 | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs200478269, COSV55626192; called by muse, mutect2, varscan2
- GSPT2 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.438); catalogued as COSV100468483, COSV61214193; called by muse, mutect2, varscan2
- H3C8 | c.134G>T p.G45V | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.187); catalogued as COSV100010091; called by muse, mutect2, varscan2
- HERC2 | c.6565G>A p.E2189K | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.034); catalogued as COSV55325904, COSV99872560; called by muse, mutect2, varscan2
- HEXIM1 | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.959); catalogued as COSV60176738; called by muse, mutect2, varscan2
- HNRNPU | c.1882C>T p.R628C (on ENST00000283179; = p.R690C on NM_004501.3) | Missense Mutation (SNP) | VAF 13/242 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV51693831; called by muse, mutect2
- HPS1 | c.260G>C p.G87A | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100282477; called by muse, mutect2
- HTR1F | c.1087C>T p.R363* | Nonsense Mutation (SNP) | VAF 13/69 reads (19%) | catalogued as rs772688320, COSV60389602; called by muse, mutect2, varscan2
- IMMP2L | c.424C>A p.L142M | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.353); catalogued as COSV100069431; called by muse, mutect2, varscan2
- IMPG2 | c.2453T>C p.L818S | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as COSV99515272; called by muse, mutect2, varscan2
- IRAG2 | c.4030G>T p.E1344* (on ENST00000636465; = p.E389* on NM_006152.4 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 6/43 reads (14%) | catalogued as rs1406986848, COSV100209175; called by muse, mutect2
- ITGAD | c.859-2A>T p.X287_splice | Splice Site (SNP) | VAF 8/40 reads (20%) | catalogued as COSV101210423; called by muse, mutect2, varscan2
- KCNC3 | c.1249C>T p.R417C | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV65387264; called by muse, mutect2, varscan2
- KLHL9 | c.1123C>T p.R375W | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs1460504347, COSV100757055; called by muse, mutect2, varscan2
- KRT71 | c.1492C>T p.R498W | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs774993798, COSV57289633; called by muse, mutect2, varscan2
- KRTAP6-1 | c.149G>T p.G50V | Missense Mutation (SNP) | VAF 20/139 reads (14%) | PolyPhen probably damaging (0.984); catalogued as COSV100228754; called by muse, mutect2, varscan2
- LGALS4 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100313376, COSV57042987; called by muse, mutect2, varscan2
- LRIF1 | c.1175G>T p.R392I | Missense Mutation (SNP) | VAF 34/294 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV100870825, COSV100870884; called by muse, mutect2, varscan2
- LRIT1 | c.1045C>A p.P349T | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.78); PolyPhen benign (0.005); catalogued as COSV100928058; called by muse, mutect2
- MACF1 | c.15553G>T p.E5185* (on ENST00000372915; = p.E3118* on NM_012090.5) | Nonsense Mutation (SNP) | VAF 5/46 reads (11%) | catalogued as COSV99243273; called by muse, mutect2
- MAP1B | c.4885G>T p.A1629S | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.142); catalogued as COSV99702150; called by muse, mutect2
- MBOAT7 | c.1270C>T p.R424W | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs376939333; called by muse, mutect2, varscan2
- MEIS3 | c.1082C>T p.S361L (on ENST00000558555 / NM_001346148.1; = p.S407L on NM_020160.3) | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.001); catalogued as COSV100520414; called by muse, mutect2, varscan2
- MME | c.2108C>T p.A703V | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); catalogued as rs200313650, COSV100852354; called by muse, mutect2
- MYH1 | c.4756G>T p.E1586* | Nonsense Mutation (SNP) | VAF 22/115 reads (19%) | catalogued as COSV56852376, COSV99875531; called by muse, mutect2, varscan2
- MYH15 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV99842908; called by muse, mutect2, varscan2
- NOP14 | c.842A>G p.E281G | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100054509; called by muse, mutect2, varscan2
- NPAP1 | c.1186C>A p.Q396K | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.038); catalogued as COSV100275112; called by muse, mutect2
- NPTX2 | c.986G>A p.G329E | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55717456; called by muse, mutect2, varscan2
- OAS1 | c.464C>T p.A155V | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0.012); catalogued as COSV99177099; called by muse, mutect2, varscan2
- OR10A2 | c.574C>G p.L192V | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.168); catalogued as COSV56300487; called by muse, mutect2, varscan2
- OR10H4 | c.878G>A p.S293N | Missense Mutation (SNP) | VAF 49/151 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs774474509, COSV59063519; called by muse, mutect2, varscan2
- OR4C12 | c.73A>C p.T25P | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as COSV100078421; called by muse, mutect2, varscan2
- OR52N1 | c.469C>A p.L157I | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.927); catalogued as COSV100398636; called by muse, mutect2, varscan2
- OR6N1 | c.593T>C p.V198A | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100625134; called by muse, mutect2, varscan2
- OSBPL11 | c.956G>C p.S319T | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV99954099; called by muse, mutect2, varscan2
- PAK1 | c.680A>G p.N227S | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV99583255; called by muse, mutect2, varscan2
- PANX1 | c.417G>C p.L139F | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV99921750; called by muse, mutect2, varscan2
- PC | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 35/270 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100852156; called by muse, mutect2, varscan2
- PCDH11X | c.146T>C p.L49S | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100010782; called by muse, varscan2
- PCDH11X | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs1462765032, COSV53441765; called by muse, varscan2
- PCDHA12 | c.1433C>T p.S478L | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.65); catalogued as rs782526620, COSV56525897; called by muse, mutect2, varscan2
- PCDHGA5 | c.1575G>C p.L525F | Missense Mutation (SNP) | VAF 21/177 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); catalogued as rs539434078, COSV99535398; called by muse, mutect2, varscan2
- PCDHGB4 | c.745G>T p.V249L | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as rs755930967, COSV99535400; called by muse, mutect2, varscan2
- PCSK2 | c.1743G>C p.K581N | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as COSV99359260; called by muse, mutect2, varscan2
- PEG3 | c.3988C>A p.P1330T | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99688357, COSV99690573; called by muse, mutect2, varscan2
- REPS2 | c.988G>C p.D330H | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100381037; called by muse, mutect2
- RNF41 | c.143C>T p.S48F | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.369); catalogued as COSV100560180; called by muse, mutect2, varscan2
- SCN10A | c.4781G>A p.R1594H | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs769338143, COSV71861262; called by muse, mutect2
- SHC1 | c.1366C>T p.R456W (on ENST00000368445 / NM_183001.5; = p.R347W on NM_003029.5) | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs747330503, COSV63534682; called by muse, mutect2, varscan2
- SLC30A10 | c.1264C>G p.L422V | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV100751471, COSV100751619, COSV63071709; called by muse, mutect2, varscan2
- TAPBPL | c.660G>C p.L220F | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.299); catalogued as COSV99869205; called by muse, mutect2, varscan2
- TENM2 | c.4915C>T p.R1639C (on ENST00000518659 / NM_001122679.2; = p.R1400C on NM_001080428.3) | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs943341943, COSV69129270; called by muse, mutect2, varscan2
- THOC2 | c.240G>A p.M80I | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV99833096; called by muse, mutect2
- TMBIM4 | c.367A>G p.I123V | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as COSV99660265; called by muse, varscan2
- TMEM131 | c.3311T>G p.L1104* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as COSV99487379; called by muse, mutect2, varscan2
- TOPBP1 | c.2180C>T p.T727M | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.066); catalogued as rs759938150, COSV53438107; called by muse, mutect2, varscan2
- TRIM71 | c.1252G>A p.V418M | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV67470059; called by muse, mutect2
- TSHZ2 | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61589158; called by muse, mutect2, varscan2
- UNC93A | c.205G>T p.G69W | Missense Mutation (SNP) | VAF 16/248 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100023017, COSV100023243; called by muse, mutect2
- VCAM1 | c.82G>C p.E28Q | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.779); catalogued as COSV54117793, COSV99658419; called by muse, mutect2
- WDR13 | c.406G>A p.V136M | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.694); catalogued as COSV54332750; called by muse, mutect2, varscan2
- WDR62 | c.3250G>A p.E1084K | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV54339362, COSV99544346; called by muse, mutect2, varscan2
- ZFC3H1 | c.4141G>T p.E1381* | Nonsense Mutation (SNP) | VAF 17/74 reads (23%) | catalogued as COSV101110470; called by muse, mutect2, varscan2
- ZFHX4 | c.7595C>G p.P2532R | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV50769242, COSV99261143; called by muse, mutect2, varscan2
- ZNF239 | c.1322G>T p.S441I | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100021757; called by muse, mutect2, varscan2
- ZNF562 | c.578T>C p.V193A (on ENST00000453372 / NM_001130032.2; = p.V121A on NM_017656.4) | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs61743320, COSV99530637; called by muse, mutect2
- ZNF569 | c.1046C>A p.T349K | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV100386402; called by muse, mutect2
- ZNF644 | c.667G>C p.E223Q | Missense Mutation (SNP) | VAF 38/221 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.116); catalogued as COSV100494381; called by muse, mutect2, varscan2
- ZNF790 | c.547T>C p.S183P | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV100764804; called by muse, mutect2, varscan2
- COPG2 | c.2236G>A p.D746N | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- DHRS11 | c.421G>A p.V141M | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- DICER1 | c.4356del p.F1452Lfs*2 | Frame Shift Del (DEL) | VAF 9/72 reads (13%) | called by mutect2, pindel, varscan2
- EP300 | c.4177_4185dup p.V1393_I1395dup | In Frame Ins (INS) | VAF 17/87 reads (20%) | called by mutect2, varscan2
- FANCB | c.1252dup p.I418Nfs*18 | Frame Shift Ins (INS) | VAF 8/90 reads (9%) | called by mutect2, pindel
- FAT1 | c.7586dup p.Y2529* | Nonsense Mutation (INS) | VAF 35/140 reads (25%) | called by mutect2, pindel, varscan2
- GABRA3 | c.1442G>T p.R481L | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2
- ZIC1 | c.592G>A p.G198R | Missense Mutation (SNP) | VAF 4/67 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2
- ACTA2 | c.168G>C p.V56= | Silent (SNP) | VAF 36/165 reads (22%) | catalogued as COSV99827025; called by muse, mutect2, varscan2
- ALPK3 | c.3075G>A p.Q1025= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV51929440, COSV99360675, COSV99361152; called by muse, mutect2, varscan2
- BICC1 | c.294C>A p.A98= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV100874816; called by muse, mutect2, varscan2
- BTN2A2 | c.1350G>A p.L450= | Silent (SNP) | VAF 10/128 reads (8%) | catalogued as COSV100760346; called by muse, mutect2
- CDC27 | c.441C>T p.F147= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as COSV99294607; called by muse, mutect2
- CUL4B | c.1893C>A p.S631= | Silent (SNP) | VAF 29/148 reads (20%) | catalogued as COSV100340365; called by muse, mutect2, varscan2
- ETS1 | c.621G>C p.S207= | Silent (SNP) | VAF 28/84 reads (33%) | catalogued as COSV100090398; called by muse, mutect2, varscan2
- FBH1 | c.1692T>C p.F564= (on ENST00000362091 / NM_178150.3; = p.F615= on NM_032807.4) | Silent (SNP) | VAF 7/119 reads (6%) | catalogued as COSV100758690; called by muse, mutect2
- FGD1 | c.1482C>A p.I494= | Silent (SNP) | VAF 6/90 reads (7%) | catalogued as COSV100911001, COSV100911224; called by muse, mutect2
- FGD5 | c.3984G>A p.S1328= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as rs765498138, COSV53249594; called by muse, mutect2
- FLG2 | c.2307C>T p.S769= | Silent (SNP) | VAF 22/478 reads (5%) | catalogued as rs769289267, COSV66167658; called by muse, mutect2
- GC | c.1125C>T p.C375= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as rs1023659662, COSV99909598; called by muse, mutect2, varscan2
- HECTD4 | c.4896C>T p.V1632= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs774151340, COSV101107213; called by muse, varscan2
- IQGAP2 | c.1377C>T p.Y459= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as COSV99166981; called by muse, mutect2, varscan2
- JCAD | c.3087G>C p.G1029= | Silent (SNP) | VAF 28/128 reads (22%) | catalogued as COSV100948267; called by muse, mutect2, varscan2
- KRT37 | c.1068C>T p.G356= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as COSV99845395; called by muse, mutect2, varscan2
- LBP | c.84C>T p.P28= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as rs149360570; called by muse, mutect2, varscan2
- LRRC14B | c.1482C>T p.F494= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV99722948; called by muse, varscan2
- MACF1 | c.15552T>A p.S5184= (on ENST00000372915; = p.S3117= on NM_012090.5) | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as COSV99243267; called by muse, mutect2
- MED12 | c.3099C>G p.T1033= | Silent (SNP) | VAF 9/89 reads (10%) | catalogued as COSV100376562, COSV100377254; called by muse, mutect2
- NAV3 | c.1572C>G p.S524= | Silent (SNP) | VAF 14/84 reads (17%) | catalogued as COSV99889368; called by muse, mutect2, varscan2
- NPAS4 | c.1455G>A p.L485= | Silent (SNP) | VAF 141/371 reads (38%) | catalogued as COSV100214946; called by muse, mutect2, varscan2
- NXPH4 | c.819C>A p.P273= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV61073617; called by muse, mutect2, varscan2
- OR1L4 | c.120G>A p.A40= | Silent (SNP) | VAF 15/176 reads (9%) | catalogued as rs1180879323, COSV52339752; called by muse, mutect2
- PCDH7 | c.102C>G p.L34= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV100687977, COSV62339241; called by muse, mutect2
- PPFIA1 | c.3516C>T p.S1172= | Silent (SNP) | VAF 25/280 reads (9%) | catalogued as rs374468603, COSV99557244; called by muse, mutect2
- RSPH4A | c.237A>G p.T79= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as rs145831200; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SCX | c.387C>T p.N129= | Silent (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- SLC13A1 | c.801G>A p.E267= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV99520722; called by muse, mutect2, varscan2
- SLC16A6 | c.408T>C p.T136= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as rs1555749436, COSV100517269; called by muse, mutect2, varscan2
- SPATA31E1 | c.1407A>C p.V469= | Silent (SNP) | VAF 24/270 reads (9%) | catalogued as COSV100350253; called by muse, mutect2
- SYNE1 | c.16815A>G p.Q5605= (on ENST00000367255 / NM_182961.4; = p.Q5534= on NM_033071.3) | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV99559835; called by muse, mutect2, varscan2
- TRIOBP | c.6633G>A p.Q2211= (on ENST00000644935 / NM_001039141.3; = p.Q498= on NM_007032.5) | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as COSV100730783; called by muse, mutect2, varscan2
- TTLL4 | c.1866C>T p.T622= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV51439352; called by muse, mutect2, varscan2
- TTN | c.18840A>G p.L6280= (on ENST00000591111; = p.L5353= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/180 reads (9%) | catalogued as COSV100604978; called by muse, mutect2
- UBE2Q1 | c.1233A>G p.K411= | Silent (SNP) | VAF 55/202 reads (27%) | catalogued as COSV99427356; called by muse, mutect2, varscan2
- UBE4B | c.96C>A p.P32= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV99476253; called by muse, mutect2, varscan2
- C15orf54 | n.779T>G | RNA (SNP) | VAF 15/124 reads (12%) | called by muse, mutect2, varscan2
- CALCA | chr11:14967797 T>G | 3'Flank (SNP) | VAF 10/93 reads (11%) | catalogued as COSV100523986; called by muse, mutect2, varscan2
- GABRA3 | c.-26-27686T>C | Intron (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100942567, COSV100942620; called by muse, mutect2, varscan2
- LINC00471 | n.383A>G | RNA (SNP) | VAF 9/95 reads (9%) | catalogued as rs747408869; called by muse, mutect2
- NBPF7 | n.170T>C | RNA (SNP) | VAF 33/107 reads (31%) | called by muse, mutect2, varscan2
